MMRF case MMRF_1940 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/e3dc30b8-ccfe-486d-964c-0237ca86591e

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 59 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 59.6 years (21,779 days); ISS stage: I; Days to last known disease status: 981 days (2.7 years); Days to last follow up: 981 days (2.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 81 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 18 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 160 days; Days to treatment end: 160 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 161 days; Days to treatment end: 161 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 291 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -5 (ECOG 1): M Protein 2.38 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.22 mg/dL; Immunoglobulin G 34.8 g/L; Immunoglobulin A 0.41 g/L; Immunoglobulin M 0.09 g/L; Beta 2 Microglobulin 1.81 µg/mL; Lactate Dehydrogenase 3.02 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.32 ×10⁹/L; Platelets 218 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.13 mmol/L; Albumin 37 g/L; Total Protein 8.8 g/dL; Glucose 16.7 mmol/L; C-Reactive Protein 0.081 mg/dL.
- Day 71: M Protein 0.57 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.42 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.9 mg/dL; Immunoglobulin G 10.4 g/L; Immunoglobulin A 0.43 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 1.51 µg/mL; Lactate Dehydrogenase 3.9 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.53 ×10⁹/L; Platelets 216 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.2 mmol/L; Albumin 38 g/L; Total Protein 6.8 g/dL; Glucose 13.5 mmol/L.
- Day 155 (ECOG 1): M Protein 0.84 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.38 mg/dL; Immunoglobulin G 15.9 g/L; Immunoglobulin A 0.57 g/L; Immunoglobulin M 0.17 g/L; Beta 2 Microglobulin 0.33 µg/mL; Lactate Dehydrogenase 2.98 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.97 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.18 mmol/L; Albumin 38 g/L; Total Protein 6.9 g/dL; Glucose 16.1 mmol/L.
- Day 260 (ECOG 1): M Protein 0.59 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.57 mg/dL; Immunoglobulin G 15.8 g/L; Immunoglobulin A 1.15 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 1.76 µg/mL; Lactate Dehydrogenase 3.37 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 168 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 7.1 g/dL; Glucose 21.3 mmol/L.
- Day 316 (ECOG 1): M Protein 0.63 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.98 mg/dL; Immunoglobulin G 14.4 g/L; Immunoglobulin A 0.86 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 1.53 µg/mL; Lactate Dehydrogenase 2.85 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 188 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 7.3 g/dL; Glucose 6.38 mmol/L.
- Day 428 (ECOG 1): M Protein 0.54 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.99 mg/dL; Immunoglobulin G 13.5 g/L; Immunoglobulin A 0.81 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 1.86 µg/mL; Hemoglobin 7.63 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.35 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 7.3 g/dL; Glucose 7.76 mmol/L.
- Day 519 (ECOG 1): M Protein 0.54 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.06 mg/dL; Immunoglobulin G 14.7 g/L; Immunoglobulin A 1 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 1.78 µg/mL; Lactate Dehydrogenase 3.37 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.33 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 7.1 g/dL; Glucose 15.8 mmol/L.
- Day 575 (ECOG 1): M Protein 0.64 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.39 mg/dL; Immunoglobulin G 16 g/L; Immunoglobulin A 0.99 g/L; Immunoglobulin M 0.48 g/L; Beta 2 Microglobulin 1.81 µg/mL; Lactate Dehydrogenase 3.33 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.05 ×10⁹/L; Platelets 159 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 7.4 g/dL; Glucose 17.7 mmol/L.
- Day 722 (ECOG 1): M Protein 0.47 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.35 mg/dL; Immunoglobulin G 17.4 g/L; Immunoglobulin A 1.01 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 1.93 µg/mL; Lactate Dehydrogenase 3.18 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 1.88 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 7.6 g/dL; Glucose 10.9 mmol/L.
- Day 841 (ECOG 0): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.01 mg/dL; Immunoglobulin G 16.2 g/L; Immunoglobulin A 1 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 0.91 µg/mL; Lactate Dehydrogenase 3.82 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.03 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 7.4 g/dL; Glucose 8.42 mmol/L.
- Day 925 (ECOG 0): M Protein 0.58 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.25 mg/dL; Immunoglobulin G 15.5 g/L; Immunoglobulin A 1.11 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 1.93 µg/mL; Lactate Dehydrogenase 3.28 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.28 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.4 mmol/L; Albumin 42 g/L; Total Protein 7.4 g/dL; Glucose 10.2 mmol/L.
- Day 981: M Protein 0.47 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.74 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.02 mg/dL; Immunoglobulin G 14.3 g/L; Immunoglobulin A 1.1 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 1.72 µg/mL; Lactate Dehydrogenase 3.13 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.43 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 7.1 g/dL; Glucose 9.46 mmol/L.

Other clinical attributes
- Day -5: Weight: 87 kg; Height: 178 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1940_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -5 days.
- Sample MMRF_1940_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -5 days.
